Somatic mutation profile of tumor specimen TCGA-77-8128-01A (aliquot TCGA-77-8128-01A-11D-2244-08) from TCGA case TCGA-77-8128, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.2 years (21,986 days).
Specimen TCGA-77-8128-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3472844b-23ea-4cb3-bfdd-44f0a3d85c5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8128-10A (Blood Derived Normal), aliquot TCGA-77-8128-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ff785be-1e48-4ca1-bd05-89f8309a522d

The open-access MAF lists 312 somatic variants for this specimen: 231 protein-altering or splice-affecting, 77 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 200, Silent 77, Nonsense Mutation 17, Frame Shift Del 6, Splice Site 5, 3'UTR 2, In Frame Del 1, Intron 1, Splice Region 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.4101C>A p.C1367* | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as COSV100383335; called by muse, mutect2, varscan2
- ADCY5 | c.2740G>A p.V914M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs781580481, COSV100568054; called by mutect2, varscan2
- ADGRB3 | c.105G>T p.K35N | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV101001410; called by muse, mutect2, varscan2
- AGMO | c.1150G>T p.D384Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100694502; called by muse, varscan2
- ALMS1 | c.9056T>C p.V3019A | Missense Mutation (SNP) | VAF 73/102 reads (72%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100043204; called by muse, mutect2, varscan2
- ANO4 | c.1451C>T p.P484L (on ENST00000392977 / NM_001286615.2; = p.P449L on NM_178826.4) | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100153412; called by muse, mutect2, varscan2
- AP3B1 | c.1040+1G>A p.X347_splice | Splice Site (SNP) | VAF 26/53 reads (49%) | catalogued as COSV99672080; called by muse, mutect2
- APBA2 | c.1141C>A p.Q381K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101258194; called by muse, mutect2, varscan2
- APOF | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100029049; called by muse, mutect2, varscan2
- ARHGAP24 | c.1448G>A p.R483H (on ENST00000395184 / NM_001025616.3; = p.R390H on NM_031305.3) | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs116009088, COSV99982248; called by muse, mutect2, varscan2
- ASPA | c.621T>A p.H207Q | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV99559275; called by muse, mutect2, varscan2
- ASPHD1 | c.343G>T p.V115F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as COSV100435662; called by muse, mutect2, varscan2
- ASXL1 | c.1836del p.T613Pfs*90 | Frame Shift Del (DEL) | VAF 28/71 reads (39%) | catalogued as COSV60125303; called by mutect2, pindel, varscan2
- ATAD5 | c.3713C>G p.A1238G | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100430107; called by muse, mutect2, varscan2
- C6 | c.2243G>T p.G748V | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as COSV54711698, COSV99667499; called by muse, mutect2, varscan2
- C9orf153 | c.97T>C p.F33L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as COSV100188715; called by muse, mutect2
- CABIN1 | c.4780C>T p.R1594W | Missense Mutation (SNP) | VAF 17/501 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV99573260; called by muse, mutect2
- CCDC102B | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV100104214; called by muse, mutect2
- CCR2 | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 188/288 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99432609; called by muse, mutect2, varscan2
- CD22 | c.2252G>A p.C751Y | Missense Mutation (SNP) | VAF 87/158 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99323558; called by muse, mutect2, varscan2
- CDH18 | c.1476T>A p.Y492* | Nonsense Mutation (SNP) | VAF 29/70 reads (41%) | catalogued as COSV99937012; called by muse, mutect2, varscan2
- CDH7 | c.1783A>C p.N595H | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.135); catalogued as COSV100542885; called by muse, mutect2, varscan2
- CDH8 | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as COSV100183310; called by muse, mutect2, varscan2
- CDH9 | c.351C>A p.D117E | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99039224; called by muse, mutect2, varscan2
- CDK1 | c.489G>A p.E163= | Splice Region (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100358887; called by muse, mutect2, varscan2
- CDKL5 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.444); catalogued as COSV101184409; called by muse, mutect2, varscan2
- CEP112 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV101210982; called by muse, mutect2, varscan2
- CGB7 | c.56G>T p.W19L | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.287); catalogued as COSV100655089; called by muse, mutect2, varscan2
- CGNL1 | c.3022A>T p.M1008L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99848780; called by muse, mutect2, varscan2
- CNGB3 | c.505G>C p.A169P | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100182600, COSV60698289; called by muse, mutect2, varscan2
- CNTNAP4 | c.1754G>C p.C585S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100272252, COSV100272491; called by muse, mutect2, varscan2
- CNTNAP5 | c.2118G>T p.R706S | Missense Mutation (SNP) | VAF 53/65 reads (82%) | SIFT tolerated (0.39); PolyPhen benign (0.033); catalogued as rs369688023; called by muse, mutect2, varscan2
- CNTNAP5 | c.2343G>T p.L781F | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101443858; called by muse, mutect2, varscan2
- COL28A1 | c.1965G>A p.M655I | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV101258817; called by muse, mutect2, varscan2
- COL4A1 | c.181G>T p.G61W | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011364, COSV101011562; called by muse, mutect2, varscan2
- CPLX2 | c.354C>A p.D118E | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); catalogued as COSV100853099; called by muse, mutect2, varscan2
- CRTC1 | c.1256C>A p.S419Y | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.347); catalogued as COSV100119466; called by muse, mutect2, varscan2
- CRYBA4 | c.229T>A p.W77R | Missense Mutation (SNP) | VAF 138/634 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100697845; called by muse, mutect2, varscan2
- CRYBB1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1400757152, COSV53232441; called by muse, mutect2, varscan2
- CSF2RB | c.2350C>T p.P784S | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as COSV99454199; called by muse, mutect2, varscan2
- CSMD3 | c.9236G>T p.R3079L (on ENST00000297405 / NM_001363185.1; = p.R2910L on NM_052900.3) | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as COSV52165093, COSV99841752; called by muse, mutect2, varscan2
- CUBN | c.7587T>A p.S2529R | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV100913174; called by muse, mutect2, varscan2
- CUBN | c.5322C>A p.N1774K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100913175; called by muse, mutect2, varscan2
- DBNDD1 | c.382G>A p.E128K (on ENST00000002501 / NM_001042610.3; = p.E148K on NM_024043.3) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99136417, COSV99136541; called by muse, mutect2, varscan2
- DCAF13 | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.047); catalogued as rs1453180772, COSV99885065; called by muse, mutect2, varscan2
- DCC | c.320A>G p.H107R | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100501864, COSV99076839; called by muse, mutect2, varscan2
- DCC | c.2282G>A p.G761D | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100501866; called by muse, mutect2, varscan2
- DCST2 | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1457406142, COSV99792115; called by muse, mutect2, varscan2
- DCX | c.530T>C p.V177A | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as CM078509, CM078513, COSV100576652; called by muse, mutect2, varscan2
- DEFB110 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV67018111; called by muse, mutect2, varscan2
- DEFB126 | c.130C>A p.H44N | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV101215679; called by muse, mutect2, varscan2
- DEPDC5 | c.2449T>A p.S817T (on ENST00000400246; = p.S886T on NM_014662.5) | Missense Mutation (SNP) | VAF 41/356 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV99836027; called by muse, mutect2, varscan2
- DGKK | c.2213C>G p.A738G | Missense Mutation (SNP) | VAF 36/47 reads (77%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV101053134; called by muse, mutect2, varscan2
- DYNC2I1 | c.1427G>C p.R476P | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101337710; called by muse, mutect2, varscan2
- EED | c.29C>G p.P10R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs780894846, COSV99646514; called by mutect2, varscan2
- EFCAB3 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV100540374; called by muse, mutect2, varscan2
- EIF2AK4 | c.1784T>G p.L595R | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99775110; called by muse, mutect2, varscan2
- EIF4G3 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs1314220663, COSV99945084; called by muse, mutect2, varscan2
- EPHA3 | c.1786T>A p.Y596N | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100347097; called by muse, mutect2, varscan2
- FAM135B | c.4116C>A p.N1372K | Missense Mutation (SNP) | VAF 162/518 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99425922; called by muse, mutect2, varscan2
- FAM155A | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.77); catalogued as rs761499834, COSV101029413; called by muse, mutect2, varscan2
- FAT3 | c.11489G>A p.G3830E | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as COSV99968326; called by muse, mutect2, varscan2
- FCRL6 | c.568C>A p.Q190K | Missense Mutation (SNP) | VAF 60/86 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs1193741004, COSV100220305; called by muse, mutect2, varscan2
- FHOD1 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 113/590 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1276907965, COSV99264122; called by muse, mutect2, varscan2
- FHOD1 | c.1580A>G p.E527G | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs2271290, COSV99264344; called by muse, mutect2, varscan2
- FLG | c.1784C>A p.A595D | Missense Mutation (SNP) | VAF 58/386 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100911881, COSV64247754; called by muse, mutect2, varscan2
- FLG | c.1082C>G p.A361G | Missense Mutation (SNP) | VAF 126/677 reads (19%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.695); catalogued as COSV100911882; called by muse, mutect2, varscan2
- FOXJ1 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.245); catalogued as COSV99487243; called by muse, varscan2
- FRY | c.8098G>T p.A2700S | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as COSV100969658; called by muse, mutect2, varscan2
- FSTL1 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.33); catalogued as rs751887286, COSV99820867; called by muse, varscan2
- GABRA6 | c.725A>T p.Y242F | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV99194755; called by muse, mutect2, varscan2
- GABRB3 | c.1163C>A p.T388N | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs1238941293, COSV100160994, COSV54666240; called by muse, mutect2, varscan2
- GALNT14 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100205210, COSV61104127; called by muse, mutect2, varscan2
- GALNT2 | c.1690A>T p.K564* | Nonsense Mutation (SNP) | VAF 21/113 reads (19%) | catalogued as COSV100795845; called by muse, mutect2, varscan2
- GBX2 | c.23C>G p.S8W | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as COSV100103590; called by muse, mutect2, varscan2
- GOT1L1 | c.919C>A p.L307M | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.69); catalogued as COSV100294623; called by muse, mutect2, varscan2
- GPC6 | c.283C>A p.R95S | Missense Mutation (SNP) | VAF 80/168 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV65500771, COSV65503817; called by muse, mutect2, varscan2
- GSX1 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as COSV100262602; called by muse, mutect2, varscan2
- HDC | c.300C>A p.N100K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV99984208; called by muse, mutect2, varscan2
- HGD | c.17A>G p.Y6C | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99381248; called by muse, mutect2, varscan2
- HOXD10 | c.693C>A p.C231* | Nonsense Mutation (SNP) | VAF 55/66 reads (83%) | catalogued as COSV99982198; called by muse, mutect2, varscan2
- HOXD10 | c.694C>A p.L232M | Missense Mutation (SNP) | VAF 55/66 reads (83%) | SIFT tolerated (0.23); PolyPhen benign (0.308); catalogued as COSV99982202; called by muse, mutect2, varscan2
- HPSE2 | c.1109C>T p.T370I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.197); catalogued as COSV100986035; called by muse, mutect2, varscan2
- HTR3E | c.385G>T p.E129* (on ENST00000415389 / NM_001256613.1; = p.E144* on NM_182589.2) | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | catalogued as COSV100094228, COSV100094311; called by muse, mutect2
- IFRD1 | c.629C>A p.S210* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV99133926, COSV99134216; called by muse, mutect2, varscan2
- IGKV1D-8 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 132/201 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as rs1450230314; called by muse, mutect2, varscan2
- IL2RB | c.760G>C p.A254P | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.555); catalogued as COSV99345073; called by muse, mutect2, varscan2
- INSC | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV101089456; called by muse, mutect2
- ITPR2 | c.2089T>C p.W697R | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777230596, COSV101190090; called by muse, varscan2
- JAKMIP1 | c.1807G>C p.V603L | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV99290319; called by muse, mutect2, varscan2
- KASH5 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101483482; called by muse, mutect2, varscan2
- KCNA5 | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99364056; called by muse, mutect2, varscan2
- KLC2 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV100270827; called by muse, mutect2, varscan2
- KMT2D | c.11038C>T p.Q3680* | Nonsense Mutation (SNP) | VAF 60/130 reads (46%) | catalogued as COSV99984337; called by muse, mutect2, varscan2
- L3MBTL4 | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99530153; called by muse, mutect2, varscan2
- LARP1B | c.1298A>T p.D433V | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99218648; called by muse, mutect2, varscan2
- LIPT1 | c.246G>T p.Q82H | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.803); catalogued as COSV100399494; called by muse, mutect2, varscan2
- LMX1A | c.960G>T p.Q320H | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99672839; called by muse, mutect2, varscan2
- LRMDA | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV100995126; called by muse, mutect2, varscan2
- LRP1B | c.9890C>A p.T3297N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV101258672; called by muse, mutect2, varscan2
- MAGEB6 | c.924G>T p.W308C | Missense Mutation (SNP) | VAF 132/168 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100983805, COSV100983928; called by muse, mutect2, varscan2
- MAGEL2 | c.3318C>A p.D1106E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.1); catalogued as COSV100046101, COSV58565708; called by muse, mutect2, varscan2
- MAP1LC3C | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100606516, COSV61803934; called by muse, mutect2, varscan2
- MAP3K5 | c.2165T>C p.L722P | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753095; called by muse, mutect2, varscan2
- MAP3K9 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV101173718; called by muse, mutect2, varscan2
- MAP7D2 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs764743272, COSV65527164; called by muse, mutect2, varscan2
- MEF2A | c.766C>G p.P256A (on ENST00000557942 / NM_001319206.2; = p.P258A on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1201466862, COSV100573870; called by muse, mutect2, varscan2
- METTL21C | c.162C>G p.S54R | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.08); catalogued as COSV99940104; called by muse, mutect2, varscan2
- MIP | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV99234367; called by muse, mutect2, varscan2
- MPEG1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs1157967756, COSV99915734; called by muse, mutect2
- MUC17 | c.12955A>C p.K4319Q | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV100074377; called by muse, mutect2, varscan2
- MUC5B | c.11542G>A p.G3848S | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs568648127, COSV71593958; called by muse, mutect2, varscan2
- MYH15 | c.3491A>T p.E1164V | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99843913; called by muse, mutect2, varscan2
- MYH7B | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.434); catalogued as rs764109123, COSV53420487, COSV99483085; called by muse, mutect2, varscan2
- MYO9B | c.3440A>G p.K1147R | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV101261743; called by muse, mutect2, varscan2
- NAV3 | c.4053C>A p.S1351R | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV99893649; called by muse, mutect2, varscan2
- NCKAP5 | c.2284A>T p.R762W | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100493565; called by muse, mutect2, varscan2
- NDFIP2 | c.700A>T p.M234L | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV99519398; called by muse, mutect2, varscan2
- NLRP8 | c.2402C>A p.T801N | Missense Mutation (SNP) | VAF 65/105 reads (62%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); catalogued as COSV52584857; called by muse, mutect2, varscan2
- NOTCH1 | c.3286G>T p.V1096L | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as COSV99490137, COSV99492261; called by muse, mutect2, varscan2
- NRAP | c.2726T>A p.M909K (on ENST00000359988 / NM_001322945.2; = p.M874K on NM_006175.4) | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs768985891, COSV100748532; called by muse, mutect2, varscan2
- NRXN1 | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.44); PolyPhen benign (0.212); catalogued as COSV101278397; called by muse, mutect2, varscan2
- NXPE4 | c.208C>A p.L70I | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV100970521; called by muse, mutect2, varscan2
- OOSP2 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV99613548; called by muse, mutect2, varscan2
- OPRK1 | c.971G>T p.S324I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV99654253; called by muse, mutect2, varscan2
- OR2AK2 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs773864972, COSV100824185, COSV63547811; called by muse, mutect2, varscan2
- OR2B2 | c.608G>C p.S203T | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV100308187; called by muse, mutect2, varscan2
- OR2D2 | c.160C>A p.Q54K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100203896; called by muse, mutect2, varscan2
- OR4C12 | c.361T>A p.Y121N | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100078615; called by muse, mutect2, varscan2
- OR51B4 | c.328G>C p.G110R | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100971699; called by muse, mutect2, varscan2
- OR51M1 | c.532T>C p.F178L | Missense Mutation (SNP) | VAF 75/271 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs1436030321, COSV100150331; called by muse, mutect2, varscan2
- OR5B2 | c.628C>A p.L210I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.098); catalogued as COSV100222921; called by mutect2, varscan2
- OR8B3 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100660385, COSV63541581; called by muse, mutect2, varscan2
- OR9Q2 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV100285489; called by muse, mutect2, varscan2
- PAPOLA | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99354460; called by muse, mutect2
- PARN | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.266); catalogued as rs185509128, COSV100421201; called by muse, mutect2, varscan2
- PCLO | c.10119G>T p.W3373C | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100435135; called by muse, mutect2, varscan2
- PCLO | c.10118G>T p.W3373L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100435146; called by muse, mutect2, varscan2
- PDHA2 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99756910; called by muse, mutect2, varscan2
- PKD1L1 | c.8000T>A p.L2667Q | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99220792; called by muse, mutect2, varscan2
- PLEKHN1 | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.523); catalogued as COSV100379222; called by muse, mutect2, varscan2
- PMM1 | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV99348216; called by muse, mutect2, varscan2
- PREX2 | c.3925G>T p.D1309Y | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV99908783; called by muse, mutect2, varscan2
- PSD | c.878T>A p.L293Q | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV99193199; called by muse, mutect2, varscan2
- PSMA8 | c.208C>A p.H70N | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.183); catalogued as rs552367990, COSV57603568; called by muse, mutect2, varscan2
- PTH | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56378690, COSV99961711; called by muse, mutect2, varscan2
- PTPRM | c.3059A>C p.K1020T | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV100159079; called by muse, mutect2, varscan2
- PTPRN2 | c.1180C>G p.R394G | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV101235017, COSV67048198; called by muse, mutect2, varscan2
- PZP | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV99738782; called by muse, mutect2, varscan2
- RAD54B | c.1260T>G p.I420M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV100280054; called by muse, mutect2, varscan2
- RALGPS2 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.739); catalogued as COSV100244157; called by muse, mutect2, varscan2
- RBMXL1 | c.443C>A p.P148Q | Missense Mutation (SNP) | VAF 109/184 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV99556681; called by muse, mutect2, varscan2
- RELN | c.389C>A p.A130D | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV100634350; called by muse, mutect2, varscan2
- RELN | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100633245; called by muse, mutect2, varscan2
- RGR | c.683G>T p.W228L | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100812938, COSV100812952; called by muse, mutect2, varscan2
- RGR | c.684G>T p.W228C | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212697754, COSV100812953; called by muse, mutect2, varscan2
- RGS22 | c.3432A>T p.E1144D | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV100693584; called by muse, mutect2, varscan2
- RHAG | c.157+1G>T p.X53_splice | Splice Site (SNP) | VAF 63/287 reads (22%) | catalogued as CS982344, COSV100006747; called by muse, mutect2, varscan2
- RIN2 | c.671A>T p.Y224F (on ENST00000255006 / NM_001242581.1; = p.Y175F on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV99657582; called by muse, mutect2, varscan2
- RIPK4 | c.2086G>T p.G696W (on ENST00000352483; = p.G648W on NM_020639.3) | Missense Mutation (SNP) | VAF 49/64 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100205201; called by muse, mutect2, varscan2
- RIPOR3 | c.1253C>G p.T418R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV99246868; called by muse, mutect2, varscan2
- RSPO3 | c.239G>C p.C80S | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100759616; called by muse, mutect2, varscan2
- RTN4RL1 | c.807G>A p.W269* | Nonsense Mutation (SNP) | VAF 7/10 reads (70%) | catalogued as rs1281492760, COSV58674621; called by muse, mutect2, varscan2
- RYR3 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs776257846, COSV66793170; called by muse, mutect2, varscan2
- SAMD9 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV101180323, COSV66075697; called by muse, mutect2, varscan2
- SAMD9L | c.755T>G p.V252G | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100560986; called by muse, mutect2, varscan2
- SCAF1 | c.1610C>T p.S537L | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as rs1470332758, COSV62184948; called by muse, mutect2
- SCAPER | c.1508G>T p.W503L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100239027; called by muse, mutect2, varscan2
- SEMA5A | c.1406G>C p.S469T | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101228555; called by muse, mutect2, varscan2
- SEMA5A | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV101228556; called by muse, mutect2, varscan2
- SENP7 | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as COSV100053620; called by muse, mutect2
- SLC16A13 | c.343+1G>A p.X115_splice | Splice Site (SNP) | VAF 146/220 reads (66%) | catalogued as rs777148419, COSV100338700, COSV57274784; called by muse, mutect2, varscan2
- SLC5A3 | c.1261A>G p.I421V | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1351204496, COSV100758011; called by muse, mutect2, varscan2
- SLCO1A2 | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 35/191 reads (18%) | catalogued as rs1180103765, COSV100262391, COSV56598952; called by muse, mutect2, varscan2
- SOX5 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100507575; called by muse, mutect2, varscan2
- SPAG9 | c.1843G>T p.E615* (on ENST00000262013 / NM_001130528.3; = p.E601* on NM_003971.6) | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100005615; called by muse, mutect2, varscan2
- SPIC | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1391380068, COSV100163024; called by muse, mutect2, varscan2
- SSUH2 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as rs763094413, COSV100436218, COSV58030836; called by muse, mutect2, varscan2
- ST8SIA5 | c.1084A>T p.S362C | Missense Mutation (SNP) | VAF 46/112 reads (41%) | PolyPhen possibly damaging (0.873); catalogued as COSV100164844; called by muse, mutect2, varscan2
- STK24 | c.820-2A>G p.X274_splice | Splice Site (SNP) | VAF 27/102 reads (26%) | catalogued as COSV100924988; called by muse, mutect2, varscan2
- STXBP2 | c.1412A>T p.Q471L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV99657283; called by muse, mutect2
- SUCLG2 | c.122A>G p.Q41R | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV100214606; called by muse, mutect2, varscan2
- SYBU | c.407A>T p.K136M (on ENST00000276646 / NM_001099754.2; = p.K135M on NM_017786.6) | Missense Mutation (SNP) | VAF 108/363 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99406474; called by muse, mutect2, varscan2
- SYCE1 | c.641G>A p.C214Y (on ENST00000343131 / NM_001143764.3; = p.C178Y on NM_130784.3) | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (1); PolyPhen possibly damaging (0.838); catalogued as rs1249849615, COSV100385907; called by muse, mutect2, varscan2
- SYN3 | c.1575G>C p.E525D | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100249642; called by muse, mutect2, varscan2
- SYNPO2 | c.1075A>T p.R359W | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100206115; called by muse, mutect2, varscan2
- TAF1C | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs1471058551, COSV100499726; called by muse, mutect2, varscan2
- TECRL | c.909C>G p.Y303* | Nonsense Mutation (SNP) | VAF 20/34 reads (59%) | catalogued as COSV101169138, COSV101169217; called by muse, mutect2, varscan2
- TG | c.8017G>C p.E2673Q | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.787); catalogued as COSV99602234; called by muse, mutect2, varscan2
- TGS1 | c.151A>G p.S51G | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99485573; called by muse, mutect2, varscan2
- TMEM132D | c.1633A>G p.I545V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV101242999; called by muse, mutect2, varscan2
- TRIM36 | c.278T>A p.I93N | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99142531; called by muse, mutect2, varscan2
- TRIM55 | c.1529del p.G510Dfs*34 (on ENST00000315962 / NM_184085.2; = p.W539* on NM_033058.3) | Frame Shift Del (DEL) | VAF 22/152 reads (14%) | catalogued as COSV52542322; called by mutect2, pindel, varscan2
- TRIM58 | c.665T>A p.L222Q | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100825210, COSV100825310; called by muse, mutect2, varscan2
- TRPM7 | c.3212G>T p.W1071L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100540119; called by muse, mutect2, varscan2
- TTN | c.45895T>C p.S15299P (on ENST00000591111; = p.S7875P on NM_003319.4) | Missense Mutation (SNP) | VAF 45/65 reads (69%) | PolyPhen probably damaging (0.997); catalogued as COSV100622523; called by muse, mutect2, varscan2
- TTN | c.25975C>A p.L8659M (on ENST00000591111; = p.L7732M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/50 reads (60%) | PolyPhen possibly damaging (0.838); catalogued as COSV100622526; called by muse, mutect2, varscan2
- TTN | c.21298C>G p.L7100V (on ENST00000591111; = p.L6173V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/152 reads (74%) | PolyPhen benign (0.001); catalogued as COSV100622527; called by muse, mutect2, varscan2
- TUBG1 | c.1121G>A p.S374N | Missense Mutation (SNP) | VAF 126/291 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as rs1467720689, COSV99258828; called by muse, mutect2, varscan2
- UGT2B10 | c.11A>C p.K4T | Missense Mutation (SNP) | VAF 58/99 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV99608561; called by muse, mutect2, varscan2
- USH2A | c.11767C>A p.L3923I | Missense Mutation (SNP) | VAF 66/81 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100239141; called by muse, mutect2, varscan2
- VPS35 | c.1713G>C p.L571F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV100140729, COSV54481187; called by muse, mutect2, varscan2
- WDR46 | c.584A>G p.Q195R | Missense Mutation (SNP) | VAF 125/178 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.177); catalogued as COSV101004818; called by muse, mutect2, varscan2
- WDR72 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267604259, COSV100854894; called by muse, mutect2, varscan2
- ZBTB41 | c.26C>G p.S9* | Nonsense Mutation (SNP) | VAF 44/77 reads (57%) | catalogued as COSV100963311; called by muse, mutect2, varscan2
- ZBTB48 | c.1685T>C p.V562A | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT tolerated (0.15); PolyPhen benign (0.169); catalogued as COSV100887271; called by muse, mutect2, varscan2
- ZC3H7B | c.2441C>G p.P814R | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.022); catalogued as COSV100687570; called by muse, mutect2, varscan2
- ZFPM2 | c.1433G>A p.R478K | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); catalogued as COSV101023337; called by muse, mutect2, varscan2
- ZNF254 | c.1550C>A p.P517H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100741727, COSV61642154; called by muse, mutect2, varscan2
- ZNF280A | c.386C>A p.S129* | Nonsense Mutation (SNP) | VAF 33/176 reads (19%) | catalogued as COSV100131150; called by muse, mutect2
- ZNF292 | c.3460G>C p.V1154L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV100370802; called by muse, mutect2, varscan2
- ZNF341 | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); catalogued as rs978326782, COSV100677953; called by muse, mutect2, varscan2
- ZNF423 | c.3232C>T p.L1078F (on ENST00000563137 / NM_001379286.1; = p.L1070F on NM_015069.4) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.603); catalogued as COSV99282936; called by muse, mutect2
- ZNF502 | c.1340A>G p.N447S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as COSV99939797; called by muse, mutect2, varscan2
- ZNF507 | c.2692A>T p.S898C | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as COSV100322015; called by muse, mutect2, varscan2
- ZNF549 | c.98C>T p.A33V (on ENST00000376233 / NM_001199295.2; = p.A20V on NM_153263.2) | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV99558691; called by muse, mutect2, varscan2
- ZNF646 | c.1531G>T p.V511L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.424); catalogued as rs1450010949, COSV100336254, COSV100336787; called by muse, mutect2, varscan2
- ZNF721 | c.2148A>T p.E716D (on ENST00000338977; = p.E728D on NM_133474.4) | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100167601; called by muse, mutect2, varscan2
- ZNF777 | c.1060G>T p.G354C | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV99925279; called by muse, mutect2, varscan2
- ZNF81 | c.536G>T p.S179I | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as CM041105, COSV58576368; called by muse, mutect2, varscan2
- ZNF883 | c.1043C>A p.P348H | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101432650; called by muse, mutect2, varscan2
- ZZZ3 | c.2508G>T p.W836C | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100890399; called by muse, mutect2, varscan2
- ADAMTS9 | c.3673del p.L1225Cfs*12 | Frame Shift Del (DEL) | VAF 23/87 reads (26%) | called by mutect2, pindel, varscan2
- AMY2A | c.582del p.I194Mfs*5 | Frame Shift Del (DEL) | VAF 98/338 reads (29%) | called by mutect2, varscan2
- COL11A1 | c.531_536del p.M178_I179del | In Frame Del (DEL) | VAF 23/38 reads (61%) | called by mutect2, pindel, varscan2
- FCGBP | c.122T>C p.L41P | Missense Mutation (SNP) | VAF 26/359 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGHE | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 26/31 reads (84%) | called by muse, mutect2, varscan2
- KDM2B | c.1197_1200del p.I399Mfs*82 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- TBC1D3B | c.388-1G>T p.X130_splice | Splice Site (SNP) | VAF 133/836 reads (16%) | called by muse, mutect2, varscan2
- TRBV29-1 | c.317_318del p.Y106Sfs*5 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | called by pindel, varscan2
- TUBA8 | c.996dup p.A333Cfs*88 | Frame Shift Ins (INS) | VAF 28/208 reads (13%) | called by mutect2, pindel, varscan2
- ABCA13 | c.13617G>T p.T4539= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV101291336, COSV101291389; called by muse, mutect2, varscan2
- ABCC8 | c.3858C>T p.Y1286= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as rs377045545; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- ADCYAP1R1 | c.789G>A p.R263= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV58449086; called by muse, mutect2, varscan2
- AFF2 | c.1446G>T p.G482= | Silent (SNP) | VAF 154/200 reads (77%) | catalogued as COSV99665354; called by muse, mutect2, varscan2
- ARPP21 | c.426G>A p.T142= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs756268326, COSV99491182, COSV99492673; called by muse, mutect2, varscan2
- BEND4 | c.777G>T p.S259= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as rs374201211; called by muse, mutect2, varscan2
- BRIX1 | c.708T>C p.F236= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100331532; called by muse, mutect2, varscan2
- CACNA1D | c.3981G>A p.V1327= (on ENST00000350061 / NM_001128840.3; = p.V1347= on NM_000720.4) | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV99859273; called by muse, mutect2, varscan2
- CCL11 | c.48C>T p.A16= | Silent (SNP) | VAF 52/168 reads (31%) | catalogued as rs746527143, COSV100005635; called by muse, mutect2, varscan2
- CEBPZ | c.225A>T p.A75= | Silent (SNP) | VAF 43/61 reads (70%) | catalogued as COSV99135689; called by muse, mutect2, varscan2
- CLVS2 | c.652C>T p.L218= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV99253283; called by muse, mutect2, varscan2
- CNGB3 | c.504G>C p.T168= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV100182604, COSV60683889; called by muse, mutect2, varscan2
- CNTN4 | c.1176T>A p.V392= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV100639495; called by muse, mutect2, varscan2
- CNTNAP4 | c.2727G>C p.L909= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV100272494; called by muse, mutect2, varscan2
- COL12A1 | c.4113C>A p.L1371= | Silent (SNP) | VAF 62/226 reads (27%) | catalogued as COSV100486280; called by muse, mutect2, varscan2
- COX4I1 | c.204C>G p.A68= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV99495512; called by muse, mutect2, varscan2
- CPEB4 | c.2028G>A p.G676= | Silent (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- CREBBP | c.6492G>C p.L2164= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV99271048; called by muse, mutect2, varscan2
- CTPS1 | c.1317C>T p.H439= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV101009371; called by muse, mutect2, varscan2
- DCAF12L2 | c.156G>A p.V52= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as COSV100758732, COSV63582827; called by muse, mutect2, varscan2
- DDX54 | c.2259A>G p.T753= | Silent (SNP) | VAF 74/193 reads (38%) | catalogued as COSV100014061; called by muse, mutect2, varscan2
- DEPDC5 | c.1119G>A p.P373= | Silent (SNP) | VAF 30/182 reads (16%) | catalogued as rs779115990, COSV56715484; ClinVar: likely benign; called by muse, mutect2, varscan2
- DGKH | c.1722C>T p.L574= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV99819275; called by muse, mutect2, varscan2
- EPHA5 | c.2337C>T p.G779= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99900174; called by muse, mutect2, varscan2
- FAM47C | c.2880C>T p.P960= | Silent (SNP) | VAF 86/111 reads (77%) | catalogued as COSV100792836; called by muse, mutect2, varscan2
- FGD6 | c.102C>A p.P34= | Silent (SNP) | VAF 59/167 reads (35%) | catalogued as COSV100676726, COSV59693241; called by muse, mutect2, varscan2
- FPGT | c.1434G>A p.K478= | Silent (SNP) | VAF 41/60 reads (68%) | catalogued as COSV100907404, COSV63837486; called by muse, mutect2, varscan2
- GALR1 | c.366C>T p.S122= | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as rs747425503, COSV100231982; called by muse, mutect2, varscan2
- HEPACAM2 | c.129C>T p.G43= (on ENST00000394468 / NM_001039372.4; = p.G31= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as rs1362751035, COSV59059852, COSV59060332; called by muse, mutect2, varscan2
- HMMR | c.699C>G p.L233= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV100701031, COSV62374993; called by muse, mutect2, varscan2
- HSD17B2 | c.1017G>A p.T339= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as rs372570633; called by muse, mutect2, varscan2
- IGLON5 | c.309G>T p.G103= | Silent (SNP) | VAF 75/117 reads (64%) | catalogued as COSV99570809; called by muse, mutect2, varscan2
- ISLR2 | c.1437C>T p.L479= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs761817111, COSV100679694; called by muse, mutect2, varscan2
- KDM4C | c.1242A>G p.E414= | Silent (SNP) | VAF 19/23 reads (83%) | catalogued as rs774043706, COSV101185024; called by muse, mutect2, varscan2
- LPCAT2 | c.1003C>T p.L335= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as COSV100045110; called by muse, mutect2, varscan2
- METTL15 | c.402G>A p.L134= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV57724813; called by muse, mutect2, varscan2
- MGAT5 | c.447T>A p.P149= | Silent (SNP) | VAF 27/40 reads (68%) | catalogued as COSV99924808; called by muse, mutect2, varscan2
- MUC16 | c.32832G>T p.V10944= | Silent (SNP) | VAF 51/91 reads (56%) | catalogued as COSV101200604; called by muse, mutect2, varscan2
- NCAM2 | c.840C>G p.V280= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99524257; called by muse, mutect2, varscan2
- NLGN4X | c.93T>C p.A31= | Silent (SNP) | VAF 45/56 reads (80%) | catalogued as rs1423274408, COSV99323093; called by muse, mutect2, varscan2
- NRG3 | c.1752A>G p.Q584= (on ENST00000404547 / NM_001370084.1; = p.Q560= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 113/215 reads (53%) | catalogued as rs774807899, COSV100932400; called by muse, mutect2, varscan2
- NT5C2 | c.1608C>G p.L536= | Silent (SNP) | VAF 50/116 reads (43%) | catalogued as COSV100583634; called by muse, mutect2, varscan2
- NTRK3 | c.2289C>A p.I763= (on ENST00000360948 / NM_001012338.2; = p.I749= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV100713383, COSV62318392; called by muse, mutect2, varscan2
- NYX | c.1275C>A p.V425= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV100699449; called by muse, mutect2, varscan2
- OLFML1 | c.330G>A p.E110= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs141873065; called by muse, mutect2, varscan2
- OR51M1 | c.78C>A p.L26= | Silent (SNP) | VAF 60/195 reads (31%) | catalogued as COSV100150330; called by muse, mutect2, varscan2
- OR52L1 | c.147G>T p.L49= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV59985575; called by mutect2, varscan2
- OR5B21 | c.105C>T p.I35= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as COSV100835165; called by muse, mutect2, varscan2
- OR5L2 | c.111C>T p.V37= | Silent (SNP) | VAF 74/294 reads (25%) | catalogued as COSV101004366; called by muse, mutect2, varscan2
- OR5L2 | c.340C>T p.L114= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as COSV101004367; called by muse, mutect2, varscan2
- PAIP1 | c.498G>A p.L166= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV100166676; called by muse, mutect2
- PLAG1 | c.930T>A p.T310= | Silent (SNP) | VAF 167/282 reads (59%) | catalogued as COSV100388079; called by muse, mutect2, varscan2
- PLEC | c.4410C>T p.Y1470= (on ENST00000322810 / NM_201380.4; = p.Y1360= on NM_000445.5) | Silent (SNP) | VAF 112/300 reads (37%) | catalogued as rs1554705980, COSV100516829; called by muse, mutect2, varscan2
- PLXNA4 | c.525C>A p.S175= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as COSV100325921; called by muse, mutect2, varscan2
- POT1 | c.51T>C p.L17= | Silent (SNP) | VAF 29/201 reads (14%) | catalogued as COSV100714106; called by muse, mutect2, varscan2
- PSD2 | c.1611T>C p.R537= | Silent (SNP) | VAF 52/85 reads (61%) | catalogued as COSV99217363; called by muse, mutect2, varscan2
- RBM19 | c.2043A>G p.E681= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV99926529; called by muse, mutect2, varscan2
- RECQL5 | c.840C>T p.S280= | Silent (SNP) | VAF 81/144 reads (56%) | catalogued as COSV100512171; called by muse, mutect2, varscan2
- RERG | c.519G>T p.V173= | Silent (SNP) | VAF 87/259 reads (34%) | catalogued as COSV99917481; called by muse, mutect2, varscan2
- RIOK2 | c.1165C>A p.R389= | Silent (SNP) | VAF 35/56 reads (63%) | catalogued as COSV99300135, COSV99300177; called by muse, mutect2, varscan2
- ROBO4 | c.2472C>A p.P824= | Silent (SNP) | VAF 52/85 reads (61%) | catalogued as rs1322932563, COSV60625345, COSV60628106; called by muse, mutect2, varscan2
- RSBN1L | c.2271T>C p.I757= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100616140; called by muse, mutect2, varscan2
- RYR3 | c.12090C>A p.R4030= (on ENST00000389232; = p.R4031= on NM_001036.6) | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as COSV101213385; called by muse, mutect2, varscan2
- SAG | c.237C>A p.I79= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV101300636, COSV101300693; called by muse, mutect2, varscan2
- SASH1 | c.1647G>A p.P549= | Silent (SNP) | VAF 70/137 reads (51%) | catalogued as rs535057612, COSV100821339; called by muse, mutect2, varscan2
- SETBP1 | c.708C>T p.F236= | Silent (SNP) | VAF 60/126 reads (48%) | catalogued as COSV99954210; called by muse, mutect2, varscan2
- SHISAL1 | c.234G>T p.A78= | Silent (SNP) | VAF 48/337 reads (14%) | catalogued as COSV101151710, COSV66988206; called by muse, mutect2, varscan2
- SI | c.4848T>C p.F1616= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100016507; called by muse, mutect2
- SLC4A1AP | c.687G>T p.P229= | Silent (SNP) | VAF 38/49 reads (78%) | catalogued as COSV100389464; called by muse, mutect2, varscan2
- SPTA1 | c.5235T>A p.L1745= | Silent (SNP) | VAF 117/148 reads (79%) | catalogued as COSV100935285; called by muse, mutect2, varscan2
- STEAP2 | c.1209G>T p.L403= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99840569; called by muse, mutect2, varscan2
- TAF4B | c.1149T>G p.S383= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV99300650; called by muse, mutect2, varscan2
- TOP3B | c.1269C>T p.D423= | Silent (SNP) | VAF 160/222 reads (72%) | catalogued as COSV100592667; called by muse, mutect2, varscan2
- TRERF1 | c.2238G>T p.T746= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100551250; called by muse, varscan2
- UGT3A1 | c.447C>T p.F149= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as rs1188793873, COSV99954498; called by muse, mutect2
- WNT9B | c.252C>T p.L84= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs548992535, COSV51519780, COSV99255030; called by muse, mutect2, varscan2
- XDH | c.3948C>G p.T1316= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as COSV101052376; called by muse, mutect2, varscan2
- IGLL3P | n.13T>C | RNA (SNP) | VAF 186/266 reads (70%) | called by muse, mutect2
- KHDRBS3 | c.*2T>C | 3'UTR (SNP) | VAF 25/58 reads (43%) | catalogued as COSV100878899; called by muse, mutect2, varscan2
- MASP1 | c.1303+5282C>G | Intron (SNP) | VAF 184/254 reads (72%) | catalogued as COSV56223167, COSV99962652; called by muse, mutect2, varscan2
- ZNF99 | c.*822T>C | 3'UTR (SNP) | VAF 14/30 reads (47%) | catalogued as rs756617267, COSV101233903; called by muse, mutect2, varscan2
